Gene-level copy-number profile of tumor specimen TCGA-FI-A2CX-01A from TCGA case TCGA-FI-A2CX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 82.7 years (30,224 days).
Specimen TCGA-FI-A2CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.8638db1c-490a-49fe-8620-68072054d3e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FI-A2CX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3fcacf66-5c4f-449e-b9fe-36dc107cec3c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 8,097; copy number 2: 45,174; copy number 3: 5,955; copy number 4: 295; copy number 6: 70; copy number 7: 78; copy number 8: 27; copy number 12: 4; copy number 24: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FI-A2CX-01A-11D-A17C-01): tumor purity 0.67, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,941,128–22,505,167, 76 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 215 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:97,215,812–99,251,223, 40 genes, copy number 12–24: LINC02253, AC020704.1, LINC02254, RN7SL677P, RNA5SP401, AC026523.2, AC026523.1, AC026523.3, AC026523.4, LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1.
- chr19:34,891,605–35,754,519, 70 genes, copy number 6 (broad region; genes not listed).
- chr22:20,652,730–21,070,097, 27 genes, copy number 8 (within-gene range 2–8): SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP.
- chr22:26,443,423–27,419,713, 35 genes, copy number 7: HPS4, SRRD, TFIP11, Z95115.1, TPST2, MIR548J, HMGB1P10, Z95115.2, CRYBB1, CRYBA4, ISCA2P1, MIAT, Z99774.5, Z99774.1, Z99774.4, Z99774.2, MIATNB, Z99774.3, LINC01422, Z97353.1, Z97353.2, AL008638.3, RNU6-1066P, AL008638.5, AL008638.4, AL008638.2, AL008638.6, AL008638.1, AL021153.1, LINC01638, AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1.
- chr22:27,978,014–29,581,327, 43 genes, copy number 7: TTC28, AL033538.1, AL033538.2, RN7SL757P, SNORD42, Y_RNA, MIR5739, RN7SL162P, CHEK2, HSCB, CCDC117, XBP1, Z93930.2, Z93930.3, Z93930.1, ZNRF3, ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P, RNU6-1219P, EMID1, RHBDD3, AL031186.1, EWSR1, GAS2L1, RASL10A, AC002059.1, AP1B1, AC002059.2, SNORD125, AC002059.3, AC000041.1, RFPL4AP6, RFPL1S, RFPL1, NEFH, AC000035.1, THOC5, AC005529.1, NIPSNAP1.

Autosomal genes at a single copy (total copy number 1): 5,676. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
